Somatic mutation profile of tumor specimen TCGA-ER-A42L-06A (aliquot TCGA-ER-A42L-06A-11D-A24R-08) from TCGA case TCGA-ER-A42L, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.5 years (21,373 days).
Specimen TCGA-ER-A42L-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3568ab2-7d2e-496f-81ae-4a693300285b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A42L-10A (Blood Derived Normal), aliquot TCGA-ER-A42L-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/875a381a-828d-4742-ac94-0b71ee106385

The open-access MAF lists 1,060 somatic variants for this specimen: 665 protein-altering or splice-affecting, 374 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 609, Silent 374, Nonsense Mutation 45, Intron 9, RNA 5, Splice Region 5, Splice Site 3, 3'Flank 2, Translation Start Site 2, 3'UTR 2, 5'Flank 2, 5'UTR 1.

Variants (750 of 1,060; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752559648, CM160492, COSV100958479, COSV66348020; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2
- A2ML1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs753186530, COSV55300039; called by mutect2, varscan2
- AAMP | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50310579; called by muse, mutect2, varscan2
- AARS2 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.653); catalogued as COSV99771299; called by muse, mutect2, varscan2
- ABCA12 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99788308, COSV99788845; called by muse, varscan2
- ABCA13 | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV70028134; called by muse, mutect2
- ABCA8 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV99285128; called by muse, mutect2, varscan2
- ABCA9 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV60622495; called by muse, mutect2
- ABCB11 | c.3560G>A p.R1187K | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99791687; called by muse, mutect2
- ABCB5 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1318774223, COSV51712789; called by muse, mutect2, varscan2
- ABCC6 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52741958; called by muse, mutect2, varscan2
- ABHD14B | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99865310; called by muse, mutect2, varscan2
- AC126283.2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs374036714, CM1311022; called by muse, mutect2
- ACAN | c.5761G>A p.A1921T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.932); catalogued as COSV100717357; called by muse, mutect2, varscan2
- ACAP1 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99341479; called by muse, mutect2, varscan2
- ACLY | c.120G>A p.W40* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as COSV100709563; called by muse, mutect2
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ACVR1C | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54647959; called by muse, mutect2
- ADAM18 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs773233943, COSV55847843; called by muse, mutect2, varscan2
- ADAM32 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65954105; called by muse, mutect2
- ADAMDEC1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56475377; called by muse, mutect2, varscan2
- ADCY1 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52033217, COSV52039137; called by muse, mutect2, varscan2
- ADGRF3 | c.2998G>A p.V1000I (on ENST00000311519 / NM_001145168.1; = p.V801I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100274849; called by muse, mutect2, varscan2
- ADGRG4 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99794736; called by muse, mutect2, varscan2
- ADGRL2 | c.3413G>A p.R1138K (on ENST00000370717 / NM_001366005.1; = p.R1125K on NM_012302.4) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54695007, COSV99587591; called by muse, mutect2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2
- ADPRH | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813285; called by muse, mutect2, varscan2
- AHNAK2 | c.5612T>A p.L1871H | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.724); catalogued as COSV100316264; called by muse, mutect2, varscan2
- AIFM3 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as rs1008206831, COSV99301436; called by muse, mutect2
- AKAP12 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99482730; called by muse, mutect2
- ALCAM | c.1704G>A p.M568I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100064423, COSV60248966; called by muse, mutect2, varscan2
- AMBRA1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs748837618, COSV100093107; called by muse, mutect2
- AMPH | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100341269, COSV57744029; called by muse, mutect2, varscan2
- ANGPTL1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1341635388, COSV99328002; called by muse, mutect2, varscan2
- ANK3 | c.10303C>T p.P3435S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.081); catalogued as COSV99778825; called by muse, mutect2
- ANK3 | c.6568G>A p.E2190K | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99778827; called by muse, mutect2
- ANKIB1 | c.1979T>C p.L660P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728583; called by muse, mutect2, varscan2
- ANKRD27 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 81/392 reads (21%) | catalogued as rs755184107, COSV100042624; called by muse, mutect2, varscan2
- ANKS3 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs113252244, COSV100422903; called by muse, mutect2, varscan2
- ANLN | c.2238T>G p.D746E | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99732014; called by muse, mutect2, varscan2
- ANO3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.734); catalogued as COSV99881314; called by muse, mutect2
- ANO4 | c.1565G>A p.G522E (on ENST00000392977 / NM_001286615.2; = p.G487E on NM_178826.4) | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54606197; called by muse, mutect2
- ARHGAP11A | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as rs570927659, COSV100853155; called by muse, mutect2, varscan2
- ARHGAP44 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99310279; called by muse, mutect2
- ARPP21 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs868511047, COSV99491327, COSV99493445; called by muse, mutect2, varscan2
- ARRB1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV100758078; called by muse, mutect2
- ASB16 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs1357024160, COSV99518784; called by muse, mutect2
- ASPRV1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57228148; called by muse, mutect2
- ASTN2 | c.2027C>T p.S676F (on ENST00000313400 / NM_001365069.1; = p.S625F on NM_014010.5) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV57761542, COSV57791174; called by muse, mutect2, varscan2
- ATF7IP | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.59); catalogued as rs1163039400; called by muse, mutect2
- ATF7IP2 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs1296861426; called by muse, mutect2
- ATP12A | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1301297307, COSV99517168; called by muse, mutect2
- ATP13A4 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV99794173; called by muse, mutect2, varscan2
- ATP13A5 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.304); catalogued as COSV60876792; called by muse, mutect2, varscan2
- ATP1A2 | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100767681; called by muse, mutect2, varscan2
- ATP2C2 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1265027320, COSV99297599; called by muse, mutect2, varscan2
- AVP | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as CM960140, COSV100977771; called by muse, mutect2
- B4GALNT3 | c.2827G>A p.G943S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842602; called by muse, mutect2, varscan2
- BBOX1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99589498; called by muse, mutect2
- BBS10 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101283362; called by muse, mutect2
- BEND2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV101191869; called by muse, mutect2, varscan2
- BEND4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); catalogued as rs771898046, COSV72468916, COSV72469273; called by mutect2, varscan2
- BHMT2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as COSV54874712; called by muse, mutect2
- BMPR2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as COSV101001332; called by muse, mutect2
- BNC1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs200106261, COSV61759322; called by muse, mutect2, varscan2
- BRCA1 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as COSV100523478; called by muse, mutect2
- BRF1 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100526946, COSV59270637; called by muse, mutect2
- BRWD1 | c.6140C>T p.S2047F | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100313029; called by muse, mutect2, varscan2
- BSN | c.9757C>T p.R3253W | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs757268879, COSV56519349; called by muse, mutect2, varscan2
- C10orf71 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV100109731; called by muse, mutect2
- C12orf40 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188977866, COSV104410247, COSV61134900, COSV61138477; called by muse, mutect2, varscan2
- C14orf39 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV100407366; called by muse, mutect2, varscan2
- C16orf46 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100215162; called by muse, mutect2, varscan2
- C16orf54 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs771166622, COSV100268423; called by mutect2, varscan2
- C1QTNF2 | c.464C>T p.P155L (on ENST00000393975; = p.P110L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV101220836; called by muse, mutect2, varscan2
- C20orf194 | c.835A>C p.T279P | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV99330401; called by muse, mutect2
- C2orf16 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV62673906; called by muse, mutect2
- C6 | c.2103G>A p.R701= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as rs1160484842, COSV54709231, COSV99666709; called by muse, mutect2
- C7 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57471459; called by muse, mutect2, varscan2
- CABIN1 | c.4000G>A p.G1334R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1355476197, COSV99572837; called by muse, mutect2
- CABIN1 | c.4001G>A p.G1334E | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99572839; called by muse, mutect2
- CABP1 | c.1018G>A p.G340R (on ENST00000316803 / NM_001033677.1; = p.G137R on NM_004276.5) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV99974564; called by muse, mutect2, varscan2
- CACNA1B | c.3782C>T p.T1261I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99495795; called by mutect2, varscan2
- CACNA1D | c.5570C>T p.S1857L (on ENST00000350061 / NM_001128840.3; = p.S1877L on NM_000720.4) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs772809958, COSV99856981; called by muse, mutect2
- CACNA1D | c.5996C>T p.P1999L (on ENST00000350061 / NM_001128840.3; = p.P2019L on NM_000720.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99856989; called by muse, varscan2
- CACNA1D | c.6068C>T p.S2023F (on ENST00000350061 / NM_001128840.3; = p.S2043F on NM_000720.4) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.284); catalogued as COSV99856991; called by muse, varscan2
- CADPS | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51900103; called by muse, mutect2
- CADPS | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99336560; called by muse, mutect2
- CALCR | c.1438C>T p.P480S (on ENST00000649521 / NM_001164737.2; = p.P464S on NM_001742.4) | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as COSV100810437; called by muse, mutect2
- CAMKV | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.1); catalogued as COSV99615228; called by muse, mutect2
- CASS4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV100824514, COSV100824575; called by muse, mutect2, varscan2
- CATSPER1 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100375710; called by muse, mutect2, varscan2
- CATSPERD | c.2214G>A p.W738* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100486695; called by muse, mutect2, varscan2
- CATSPERG | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV99286199; called by muse, mutect2, varscan2
- CBX2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs782371642, COSV99490779; called by muse, mutect2
- CC2D2B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100729324; called by muse, mutect2
- CCBE1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); catalogued as rs868101186, COSV67949619; called by muse, mutect2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCDC185 | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100838764; called by muse, mutect2, varscan2
- CCDC88C | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344423369, COSV66236896; called by muse, mutect2
- CCL26 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99139124; called by muse, mutect2
- CCNL1 | c.1063T>G p.S355A | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99904416; called by muse, mutect2
- CCRL2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 48/496 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV100644984; called by muse, mutect2
- CCT5 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99725164; called by muse, mutect2, varscan2
- CD163L1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100549805, COSV58022236; called by mutect2, varscan2
- CD163L1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80190863, COSV100549806; called by muse, mutect2, varscan2
- CD1A | c.120G>A p.W40* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as rs866676954, COSV99192238; called by muse, mutect2, varscan2
- CD2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as rs1024165793, COSV65643478; called by muse, mutect2
- CD4 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.562); catalogued as COSV50589182; called by muse, mutect2, varscan2
- CD93 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV99848991; called by muse, mutect2
- CDH16 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100233719; called by muse, mutect2, varscan2
- CDH6 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV54080903; called by muse, mutect2
- CEACAM7 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as rs1263780551, COSV99137153; called by muse, mutect2
- CEACAM8 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as rs985625692, COSV99747478; called by muse, mutect2
- CFAP70 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | catalogued as rs1306301088, COSV60283268; called by muse, mutect2
- CHRM3 | c.1326C>G p.D442E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV55081684, COSV99697747; called by muse, mutect2, varscan2
- CIAO1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV99302514; called by muse, mutect2, varscan2
- CIT | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1170481676, COSV99948797; called by muse, mutect2, varscan2
- CLCN2 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99658328; called by muse, mutect2, varscan2
- CLDN11 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50355473; called by muse, mutect2, varscan2
- CLEC4C | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.528); catalogued as rs867782925, COSV100665342; called by muse, mutect2, varscan2
- CLEC4D | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs946297864, COSV55230883; called by muse, mutect2, varscan2
- CLK1 | c.391-1G>A p.X131_splice | Splice Site (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100362179; called by muse, mutect2, varscan2
- CLU | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100324166, COSV57065718; called by muse, mutect2, varscan2
- COBLL1 | c.959C>T p.S320F (on ENST00000392717; = p.S282F on NM_014900.5) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99527495; called by muse, mutect2, varscan2
- COG3 | c.898T>A p.F300I | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1466658534, COSV100596428; called by muse, mutect2
- COL12A1 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59403457; called by muse, mutect2
- COL15A1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100897502; called by mutect2, varscan2
- COL16A1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as rs1394952329, COSV99593766; called by muse, mutect2, varscan2
- COL19A1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59578306; called by muse, mutect2
- COL19A1 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752857777, COSV59575112; called by muse, mutect2, varscan2
- COL1A2 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99798885; called by muse, mutect2
- COL1A2 | c.3106G>A p.G1036S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as CM070870, COSV99800184; called by muse, mutect2
- COL23A1 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101178276; called by muse, mutect2
- COL3A1 | c.3657T>A p.Y1219* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100482660; called by muse, mutect2
- COL4A3 | c.2785A>G p.T929A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100516671; called by muse, mutect2, varscan2
- COL4A4 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61630562, COSV61636519; called by muse, mutect2, varscan2
- COL4A5 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1349831065, COSV60371467; called by mutect2, varscan2
- COL4A5 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as CD115550, COSV60364536; called by muse, mutect2, varscan2
- COP1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100442927; called by muse, mutect2, varscan2
- COQ7 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100430475; called by muse, mutect2, varscan2
- COX7B2 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100260303; called by muse, mutect2, varscan2
- CPB1 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV51571356; called by muse, mutect2, varscan2
- CPED1 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1330057265, COSV100120040; called by muse, mutect2, varscan2
- CRACD | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV99949696, COSV99950181; called by muse, mutect2
- CRADD | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.303); catalogued as COSV60556713; called by muse, mutect2
- CRB1 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs930465675, COSV100958480; ClinVar: uncertain significance; called by muse, mutect2
- CRYZ | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61716986; called by muse, mutect2
- CSMD1 | c.9506G>A p.G3169E (on ENST00000520002; = p.G3168E on NM_033225.6) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100145120; called by muse, mutect2, varscan2
- CSMD1 | c.6283C>T p.Q2095* (on ENST00000520002; = p.Q2094* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 8/137 reads (6%) | catalogued as rs866880226, COSV100145121; called by muse, mutect2
- CSMD3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748518371, COSV99827926; called by muse, mutect2, varscan2
- CTDP1 | c.2189A>T p.D730V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99310239; called by muse, mutect2
- CTNNA3 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1060502222, COSV65560206; ClinVar: uncertain significance; called by muse, mutect2
- CUX1 | c.3349C>T p.Q1117* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | catalogued as COSV99470801; called by muse, mutect2
- CYRIA | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV100838258; called by muse, mutect2, varscan2
- DAB2IP | c.2438C>T p.S813F (on ENST00000408936; = p.S785F on NM_032552.3) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV99404930; called by muse, mutect2
- DCC | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV71437045; called by muse, mutect2, varscan2
- DCDC1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1225204688, COSV100662912; called by muse, mutect2
- DDX53 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.173); catalogued as COSV60069545; called by muse, mutect2, varscan2
- DENND3 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.495); catalogued as rs1402162783; called by muse, mutect2
- DGKI | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 29/341 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs767973885, COSV99932910; called by muse, mutect2
- DGKQ | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1291375104, COSV53279295, COSV99297601; called by muse, mutect2, varscan2
- DHX32 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | catalogued as COSV99501460; called by muse, mutect2
- DHX57 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99769183; called by muse, mutect2
- DIDO1 | c.6178G>A p.E2060K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV56631168; called by muse, mutect2
- DISP3 | c.4025G>A p.G1342D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs141052083, COSV53839665; called by muse, mutect2, varscan2
- DLGAP3 | c.2492A>G p.E831G | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV99332335; called by muse, mutect2
- DMBX1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100760695; called by muse, mutect2, varscan2
- DMXL2 | c.5141C>T p.S1714F | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51855939; called by muse, mutect2, varscan2
- DNAH11 | c.11575G>T p.E3859* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV100177923, COSV60957746; called by muse, mutect2
- DNAH2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV101209086; called by muse, mutect2
- DNAH5 | c.11561C>T p.S3854F | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs185212802, COSV99446290; called by muse, mutect2
- DNAH5 | c.10875C>T p.I3625= | Splice Region (SNP) | VAF 21/125 reads (17%) | catalogued as rs772138612, COSV54223956; called by muse, mutect2, varscan2
- DNAH5 | c.9655G>A p.A3219T | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs1554040804, COSV99446294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.7399C>T p.P2467S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV54245960, COSV54249052; called by muse, mutect2, varscan2
- DNAH5 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV99446296; called by muse, mutect2, varscan2
- DNAH7 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760420578, COSV100414288; called by muse, mutect2
- DNAH8 | c.12791G>A p.R4264K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100543818, COSV100544619; called by muse, mutect2
- DOC2A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58751098; called by muse, mutect2, varscan2
- DPH5 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV100587368; called by muse, mutect2
- DPP10 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs764715614, COSV59662512; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DQX1 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV101098829; called by muse, mutect2
- DSCAM | c.5638G>A p.D1880N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68019988; called by muse, mutect2, varscan2
- DSCAM | c.5038G>A p.D1680N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV68032482; called by muse, mutect2, varscan2
- DSP | c.8260G>A p.G2754R | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV100672907; called by muse, mutect2
- DST | c.5075C>T p.S1692F | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99752509; called by muse, mutect2
- DUSP4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99529663; called by muse, mutect2, varscan2
- DYRK4 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50540119; called by muse, mutect2
- E2F5 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99809356; called by muse, mutect2, varscan2
- ECRG4 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99430241; called by muse, mutect2
- EDARADD | c.154C>T p.P52S (on ENST00000334232 / NM_145861.4; = p.P42S on NM_080738.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1259703946, COSV100512600; called by muse, mutect2, varscan2
- EGFR | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs778011429, COSV99287971; called by muse, mutect2
- EGR4 | c.1147G>A p.A383T (on ENST00000545030; = p.A280T on NM_001965.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1251234337; called by muse, mutect2
- EIF3E | c.1121T>A p.L374* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99622887; called by muse, mutect2, varscan2
- ELAPOR2 | c.2653G>A p.E885K (on ENST00000450689 / NM_001142749.3; = p.E718K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV99788357; called by muse, mutect2, varscan2
- ELMO2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99281511; called by muse, mutect2, varscan2
- EMG1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781002; called by muse, mutect2, varscan2
- ENDOD1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99566409; called by muse, mutect2
- ENTPD1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs1322433809, COSV64600078; called by muse, mutect2
- EP300 | c.6624T>A p.H2208Q | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.162); catalogued as COSV99607752; called by muse, mutect2
- EPHA4 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99915908; called by muse, mutect2, varscan2
- ERAS | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs1185068643, COSV99504778; called by muse, mutect2
- ERBB4 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as rs1438732641, COSV61477133; called by muse, mutect2
- ERICH3 | c.4001G>A p.G1334E | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV100443693; called by muse, mutect2, varscan2
- ERICH3 | c.3092G>A p.G1031E | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100443695; called by muse, mutect2
- ERN2 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.125); catalogued as rs149889613; called by muse, mutect2, varscan2
- EXD1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100153529; called by muse, mutect2, varscan2
- F5 | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100888981; called by muse, mutect2
- FAM131B | c.527-1G>A p.X176_splice | Splice Site (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100577726, COSV100577805; called by muse, mutect2
- FAM135B | c.3932T>C p.V1311A | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99420601; called by muse, mutect2
- FAM83B | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV60927123; called by muse, mutect2, varscan2
- FAT3 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV53183712, COSV99959488; called by muse, mutect2
- FCAMR | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61366750; called by muse, mutect2, varscan2
- FCRL5 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100708640; called by muse, mutect2, varscan2
- FCRL5 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.903); catalogued as COSV62514007; called by muse, mutect2
- FLG2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV101165662; called by muse, mutect2
- FLNC | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.242); catalogued as COSV100367740; called by muse, mutect2
- FOXJ1 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99486712; called by muse, mutect2
- FRAS1 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs868317389; called by muse, mutect2
- FRMPD1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100899412; called by muse, mutect2, varscan2
- FURIN | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.445); catalogued as COSV99184627; called by muse, mutect2, varscan2
- GABRB3 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.562); catalogued as COSV100158704; called by muse, mutect2, varscan2
- GAL3ST1 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100142964; called by muse, mutect2
- GALNT17 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as COSV61185135; called by muse, mutect2
- GARNL3 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100150035; called by muse, mutect2
- GBA3 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); catalogued as COSV101545484; called by muse, mutect2, varscan2
- GBP2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV100975358; called by muse, mutect2, varscan2
- GDF3 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as rs919959443, COSV100325157; called by muse, mutect2, varscan2
- GEM | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); catalogued as rs1237330383, COSV52597459; called by muse, mutect2, varscan2
- GFRAL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868599487, COSV61228767, COSV61234756; called by muse, mutect2, varscan2
- GIMAP8 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56232371; called by muse, mutect2
- GLI3 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV101229764; called by muse, mutect2
- GOLGB1 | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV61472957; called by muse, mutect2
- GPATCH8 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100132516; called by muse, mutect2
- GPC5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65576303; called by muse, mutect2
- GPC5 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs1449780201, COSV65632007; called by muse, mutect2
- GRB7 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.039); catalogued as COSV100485407; called by muse, mutect2
- GRIP2 | c.3241C>T p.P1081S (on ENST00000619221; = p.P984S on NM_001080423.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1295940650, COSV99817048; called by muse, mutect2
- GRM8 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV58800748; called by muse, mutect2, varscan2
- GSDMC | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV52693198; called by muse, mutect2
- GSDMC | c.99A>C p.L33F | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99415696; called by muse, mutect2, varscan2
- GSTK1 | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100621755; called by muse, mutect2, varscan2
- GTF3C2 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV53124434; called by muse, mutect2
- GTF3C2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1397085676, COSV99272332; called by muse, mutect2, varscan2
- GUCA1A | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99273858; called by muse, mutect2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2
- GUCY2C | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV53792123; called by muse, mutect2
- HARBI1 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100454685; called by muse, mutect2, varscan2
- HCN1 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100299142; called by muse, mutect2, varscan2
- HEATR1 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100857519; called by muse, mutect2, varscan2
- HECW1 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs775546507, COSV67830526; called by muse, mutect2, varscan2
- HRC | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs201631525, COSV99417645; called by muse, mutect2
- HSD17B6 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100444226; called by muse, mutect2, varscan2
- HTR1A | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100108983; called by muse, mutect2
- HTRA4 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56759640; called by muse, mutect2, varscan2
- ICE1 | c.5776T>C p.S1926P | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as COSV99664061; called by muse, mutect2
- IFIT1B | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1455026168, COSV65663819; called by muse, mutect2
- IGHV3-21 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.165); catalogued as rs782419151; called by muse, mutect2, varscan2
- IGHV3-35 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.119); catalogued as rs772586386; called by muse, mutect2, varscan2
- IGKV1-8 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1336077720; called by muse, mutect2, varscan2
- IGKV1D-8 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as rs766525464; called by muse, mutect2, varscan2
- IGLV2-23 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as rs749296050; called by muse, mutect2
- IGSF10 | c.7395A>T p.K2465N | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.499); catalogued as COSV99177018; called by muse, mutect2
- IL20RA | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759117119, COSV100359851; called by muse, mutect2, varscan2
- ILDR1 | c.1444G>A p.E482K (on ENST00000344209 / NM_001199799.2; = p.E438K on NM_175924.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV99878064; called by muse, mutect2, varscan2
- INAVA | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100949907; called by muse, mutect2, varscan2
- IQCJ | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV101188130; called by muse, mutect2, varscan2
- IRAG1 | c.2247G>C p.K749N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV101350983; called by muse, mutect2
- IRAK3 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99706001; called by muse, mutect2
- IRAK3 | c.1299A>C p.R433S | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99706002; called by muse, mutect2
- ISLR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs868123537, COSV99997227; called by muse, mutect2, varscan2
- ISM2 | c.1106C>T p.S369F (on ENST00000342219 / NM_199296.3; = p.P254S on NM_182509.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs950218728, COSV99376509; called by muse, mutect2, varscan2
- ITGA11 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1485083324, COSV59875405; called by muse, mutect2, varscan2
- ITGA4 | c.1279T>G p.L427V | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99275869; called by muse, mutect2
- ITGB4 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.279); catalogued as COSV99563567; called by muse, mutect2
- ITGB8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV56011827; called by muse, mutect2, varscan2
- ITM2A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64810927; called by muse, mutect2, varscan2
- ITPRID1 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV100085877; called by muse, mutect2, varscan2
- KANSL3 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as COSV100830964; called by muse, mutect2
- KCNB1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV100870407; called by muse, mutect2
- KCNB2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV73048711; called by muse, mutect2, varscan2
- KCNH5 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100525701; called by muse, mutect2
- KCNK9 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57289093; called by muse, mutect2, varscan2
- KCNMB2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750779813, COSV100843871; called by muse, mutect2, varscan2
- KDM2B | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100997284; called by muse, mutect2
- KEL | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV62333730; called by muse, mutect2, varscan2
- KIAA1217 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs764849456, COSV56814128; called by muse, mutect2, varscan2
- KIF11 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99585690; called by muse, mutect2
- KIF13A | c.1107A>T p.E369D | Missense Mutation (SNP) | VAF 15/372 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as COSV99434578; called by muse, mutect2
- KIF1A | c.3671C>T p.S1224F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100240113; called by muse, mutect2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2
- KIF3B | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs1331386508, COSV100996343; called by mutect2, varscan2
- KIFBP | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV100741358; called by muse, mutect2, varscan2
- KIR2DL1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.348); catalogued as rs1280526048, COSV99382796; called by muse, mutect2
- KIR3DL1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 23/472 reads (5%) | catalogued as rs201727627, COSV100428379; called by muse, mutect2
- KLRG2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100572470; called by muse, mutect2
- KRT74 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99977427; called by muse, mutect2, varscan2
- KRTAP5-3 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.897); catalogued as rs763390059, COSV101294496; called by muse, mutect2, varscan2
- KY | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101414957; called by muse, mutect2, varscan2
- L1CAM | c.3671C>T p.S1224L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981159, COSV99055184; called by muse, mutect2
- LAMB2 | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100025921; called by muse, mutect2
- LAT2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as rs1252988686, COSV51920997, COSV51922347; called by muse, mutect2
- LATS1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV99485472; called by muse, mutect2
- LGR6 | c.2588C>T p.S863F (on ENST00000367278 / NM_001017403.1; = p.S811F on NM_021636.3) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368839488; called by muse, mutect2, varscan2
- LILRA2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV99252965; called by muse, mutect2
- LIN28B | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61496766; called by muse, mutect2
- LIPK | c.888G>A p.Q296= | Splice Region (SNP) | VAF 4/62 reads (6%) | catalogued as COSV101344958; called by muse, mutect2
- LIX1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.431); catalogued as COSV57207855; called by muse, mutect2, varscan2
- LRFN5 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV53243984; called by muse, mutect2, varscan2
- LRIG2 | c.2332C>T p.H778Y | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as COSV100743062; called by muse, mutect2
- LRP1 | c.5410C>T p.Q1804* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs1555185053, COSV54503425; called by muse, mutect2, varscan2
- LRP2 | c.12875G>A p.G4292E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99787018; called by muse, mutect2, varscan2
- LRP4 | c.2094G>A p.G698= | Splice Region (SNP) | VAF 7/103 reads (7%) | catalogued as COSV66138619, COSV66138966; called by muse, mutect2
- LRPAP1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99578830; called by muse, mutect2
- LRRN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267599792, COSV60013540; called by muse, mutect2
- MACROH2A2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57158606; called by muse, mutect2
- MAGEB6B | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs368301154; called by muse, mutect2, varscan2
- MAGEC1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99595109; called by muse, mutect2
- MAGEC1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1469473688, COSV53567904; called by muse, varscan2
- MANBA | c.1942C>T p.H648Y (on ENST00000642252; = p.H602Y on NM_005908.4) | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV56965795, COSV99898456; called by muse, mutect2, varscan2
- MAP3K5 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100752591; called by muse, mutect2
- MARCHF1 | c.396G>A p.M132I (on ENST00000274056; = p.M115I on NM_017923.4) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV56815765, COSV56825611; called by muse, mutect2
- MARVELD2 | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV100347447; called by muse, mutect2
- MBD5 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759958775, COSV68696821; called by muse, mutect2, varscan2
- MBD5 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV101289972; called by muse, mutect2, varscan2
- MDN1 | c.9044C>T p.S3015F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101020910; called by muse, mutect2
- MECOM | c.1900C>T p.P634S (on ENST00000468789 / NM_001105078.4; = p.P822S on NM_004991.4) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52965270; called by muse, mutect2, varscan2
- MED12L | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs1207782214, COSV56377068, COSV99851990; called by muse, mutect2, varscan2
- MED12L | c.4226G>A p.R1409K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV99851991; called by muse, mutect2, varscan2
- MED13L | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99928113; called by muse, mutect2, varscan2
- MGA | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99578923; called by muse, mutect2, varscan2
- MLXIP | c.2448G>A p.M816I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100038528; called by muse, mutect2, varscan2
- MMD2 | c.622G>A p.G208S (on ENST00000404774 / NM_001100600.2; = p.G184S on NM_198403.4) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101286953; called by muse, mutect2, varscan2
- MOXD1 | c.1720T>A p.Y574N | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV100381333; called by muse, mutect2
- MPL | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100991401; called by muse, mutect2
- MRPL30 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.369); catalogued as COSV100585362; called by muse, mutect2
- MSH4 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54202368, COSV99590995; called by muse, mutect2, varscan2
- MTMR11 | c.473C>T p.T158I (on ENST00000439741 / NM_001145862.2; = p.T86I on NM_181873.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs376785714; called by muse, mutect2, varscan2
- MTOR | c.7270G>A p.D2424N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63870279, COSV63875723; called by muse, mutect2
- MUC16 | c.29266C>T p.P9756S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); catalogued as COSV67451110; called by muse, mutect2
- MUC16 | c.27872T>G p.M9291R | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101198731; called by muse, mutect2
- MUC16 | c.22966G>A p.G7656R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1243076399, COSV67477318; called by muse, mutect2, varscan2
- MUC16 | c.21677C>T p.S7226L | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.351); catalogued as COSV101200634; called by muse, mutect2
- MUC17 | c.10178G>A p.S3393N | Missense Mutation (SNP) | VAF 108/898 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100072154, COSV60288997; called by muse, mutect2, varscan2
- MYH15 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99842591; called by muse, mutect2, varscan2
- MYH7 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as rs397516117, COSV62516619, COSV62523490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100805817; called by muse, mutect2
- MYLK | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375731554; called by muse, mutect2, varscan2
- MYOM3 | c.3341G>A p.W1114* | Nonsense Mutation (SNP) | VAF 23/234 reads (10%) | catalogued as COSV100141595; called by muse, mutect2, varscan2
- MYRIP | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV100218537; called by muse, mutect2
- NAALADL2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758191201, COSV101379971; called by muse, mutect2, varscan2
- NAALADL2 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101495211; called by muse, mutect2, varscan2
- NCKAP1L | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.267); catalogued as rs762723962, COSV53206062; called by mutect2, varscan2
- NDC1 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323372; called by muse, mutect2
- NDRG4 | c.109C>A p.H37N (on ENST00000570248 / NM_001378344.1; = p.H69N on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99261786; called by muse, mutect2, varscan2
- NEB | c.11356G>A p.D3786N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99416992; called by muse, mutect2, varscan2
- NEK11 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100797591; called by muse, mutect2, varscan2
- NELL2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369537621; called by muse, mutect2, varscan2
- NEXMIF | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50027658; called by muse, mutect2, varscan2
- NEXMIF | c.664A>C p.K222Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99280044; called by muse, mutect2, varscan2
- NFASC | c.2539C>T p.H847Y (on ENST00000339876 / NM_001378329.1; = p.H950Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58371970; called by muse, mutect2
- NFRKB | c.3868C>T p.P1290S (on ENST00000446488 / NM_001143835.2; = p.P1315S on NM_006165.3) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV99859265; called by muse, mutect2
- NKG7 | c.190A>C p.M64L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99389820; called by muse, mutect2
- NLRC5 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs775715527, COSV99346700; called by muse, mutect2, varscan2
- NLRP3 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100276155, COSV60220473; called by muse, mutect2, varscan2
- NLRP4 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708423; called by muse, mutect2, varscan2
- NLRP7 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs541228827, COSV60182563; called by muse, mutect2
- NLRP8 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52591991; called by muse, mutect2
- NLRP8 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1461331084, COSV99404880; called by muse, mutect2, varscan2
- NPR3 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV54089648; called by muse, mutect2, varscan2
- NRXN1 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs796052776, COSV58448967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58463010; called by muse, mutect2, varscan2
- NUAK2 | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV65681342; called by muse, mutect2
- NUCB2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100082626; called by muse, mutect2
- NUP155 | c.3421C>T p.L1141F (on ENST00000231498 / NM_153485.3; = p.L1082F on NM_004298.4) | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51527377, COSV99193777; called by muse, mutect2, varscan2
- NWD1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100341918; called by muse, mutect2, varscan2
- NYAP1 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs768207302, COSV55718562; called by muse, mutect2, varscan2
- OCEL1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99285643; called by muse, mutect2, varscan2
- ONECUT2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101525695; called by muse, mutect2
- OPRK1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55569122; called by muse, mutect2, varscan2
- OR10AG1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs866761699, COSV100400175, COSV56631311; called by muse, mutect2
- OR13C5 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs267602070, COSV66164546; called by muse, mutect2
- OR2A14 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376721058; called by muse, mutect2
- OR2A14 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs1323672350, COSV101376445; called by muse, mutect2, varscan2
- OR2F1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748122563, COSV67331053; called by muse, mutect2, varscan2
- OR2G6 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 44/196 reads (22%) | catalogued as rs997307850, COSV100598054, COSV58574350, COSV58574803; called by muse, mutect2, varscan2
- OR4A15 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.452); catalogued as rs1395992120, COSV100123898, COSV59037025; called by muse, mutect2
- OR4C46 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV60218688; called by muse, mutect2, varscan2
- OR4K15 | c.103G>A p.E35K (on ENST00000305051; = p.E11K on NM_001005486.1) | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV59303318; called by muse, mutect2
- OR4K2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV53848749, COSV53848767; called by muse, mutect2
- OR51G1 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as COSV58969324, COSV58969611; called by muse, mutect2
- OR5AK2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100475936; called by muse, mutect2
- OR5H15 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV100736629, COSV62948288; called by muse, mutect2, varscan2
- OR5K1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs751287401, COSV100220890; called by muse, mutect2, varscan2
- OR5M11 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs754849517, COSV73141718, COSV73141748; called by muse, mutect2
- OR5T1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143790336; called by muse, mutect2
- OR5T2 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as COSV57588413, COSV57589179; called by muse, mutect2
- OR6C3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs866375503, COSV65570631; called by muse, mutect2, varscan2
- OR6C6 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64455527; called by muse, mutect2
- OVGP1 | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100868035; called by muse, mutect2
- OXGR1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.291); catalogued as rs779950415, COSV53658138; called by mutect2, varscan2
- PADI4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100966718; called by muse, mutect2, varscan2
- PAK3 | c.1552G>A p.D518N (on ENST00000262836 / NM_001324328.2; = p.D503N on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV99456715; called by muse, mutect2, varscan2
- PAK5 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV62037415; called by muse, mutect2, varscan2
- PALLD | c.1623C>A p.A541= | Splice Region (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99824139; called by muse, mutect2
- PAM | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs753227077, COSV99173152; called by muse, mutect2, varscan2
- PAPOLG | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53182937; called by muse, mutect2, varscan2
- PAPPA2 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62783918; called by muse, mutect2
- PAQR9 | c.880A>T p.K294* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100503724; called by muse, mutect2, varscan2
- PARP16 | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99975340; called by muse, mutect2, varscan2
- PCDHA4 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs267600386, COSV63538765; called by muse, mutect2, varscan2
- PCDHAC1 | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV99165243; called by muse, mutect2
- PCDHAC1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); catalogued as COSV99144990; called by muse, mutect2
- PCDHB1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782739946, COSV60630334; called by muse, mutect2
- PCDHB11 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV53378112; called by muse, mutect2
- PCDHB13 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 25/277 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.151); catalogued as COSV99506946; called by muse, mutect2
- PCDHB15 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.222); catalogued as rs782508898, COSV99178848; called by muse, mutect2, varscan2
- PCDHGA1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs769162898, COSV65294845; called by muse, mutect2
- PCF11 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100017977, COSV53537200; called by muse, mutect2, varscan2
- PCOLCE2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55998262; called by muse, mutect2, varscan2
- PCSK9 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100134988; called by muse, mutect2
- PDCD2L | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99874905; called by muse, mutect2
- PDILT | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as rs753631150; called by muse, mutect2, varscan2
- PDP1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); catalogued as rs1194411687, COSV52601152; called by muse, mutect2, varscan2
- PDZD2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99224168; called by muse, mutect2, varscan2
- PEG3 | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as COSV99687820; called by muse, mutect2
- PHGDH | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101025053; called by muse, mutect2, varscan2
- PILRB | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs1201794415, COSV60333160; called by muse, mutect2
- PKHD1L1 | c.5621C>T p.S1874F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as COSV65749538; called by muse, mutect2, varscan2
- PLPP4 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100956231; called by muse, mutect2, varscan2
- PLPPR1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100883116; called by muse, mutect2, varscan2
- PLS1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100537991; called by muse, mutect2, varscan2
- PLS1 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100537993; called by muse, mutect2
- PLXNA4 | c.3901C>T p.H1301Y | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.589); catalogued as COSV58164668; called by muse, mutect2, varscan2
- PLXNA4 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100323076; called by muse, mutect2, varscan2
- PNLDC1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99277223; called by muse, mutect2
- PPARGC1A | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99337472; called by muse, mutect2
- PPP1R9A | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56909898; called by muse, mutect2, varscan2
- PRAG1 | c.2248G>A p.G750S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.437); catalogued as COSV100421963; called by muse, mutect2, varscan2
- PRKG1 | c.1898G>A p.W633* | Nonsense Mutation (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100907180; called by muse, mutect2
- PRPF3 | c.1987A>G p.K663E | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100254586; called by muse, mutect2, varscan2
- PRRC2C | c.722C>T p.S241F (on ENST00000367742; = p.S239F on NM_015172.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs945764126, COSV100144852; called by muse, mutect2, varscan2
- PRRG3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV64850928; called by muse, mutect2, varscan2
- PRRT3 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99926404; called by muse, mutect2, varscan2
- PRX | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52534316; called by muse, mutect2
- PSKH2 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201080415; called by muse, mutect2, varscan2
- PSMA4 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99245439; called by muse, varscan2
- PTCHD3 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867095373, COSV71256798; called by muse, mutect2
- PTGS1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99792980; called by muse, mutect2, varscan2
- PTPRC | c.3719A>G p.N1240S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100722252; called by muse, mutect2, varscan2
- PTPRN2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67020941; called by muse, mutect2, varscan2
- PTPRT | c.3100-1G>A p.X1034_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100625956; called by muse, mutect2, varscan2
- PUS7 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV100708468; called by muse, mutect2
- PWWP3B | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61801797; called by muse, mutect2
- PXDNL | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs757058225, COSV62485102; called by muse, mutect2, varscan2
- PYGB | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99404903, COSV99404918; called by muse, mutect2
- RAG1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100200739; called by muse, mutect2
- RAI2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100518126, COSV58966580; called by muse, mutect2, varscan2
- RBM22 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV52270634; called by muse, mutect2
- RCC2 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64906558; called by muse, mutect2, varscan2
- RFPL3 | c.223G>A p.D75N (on ENST00000249007 / NM_001098535.1; = p.D46N on NM_006604.2) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs759338505, COSV99966953; called by muse, mutect2, varscan2
- RFT1 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99965361; called by muse, mutect2, varscan2
- RFX4 | c.2150A>C p.Q717P (on ENST00000392842 / NM_213594.3; = p.Q623P on NM_032491.6) | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99985524; called by muse, mutect2
- RGS22 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100693059; called by muse, mutect2, varscan2
- RGS3 | c.2197G>A p.E733K (on ENST00000350696 / NM_001282923.2; = p.E452K on NM_130795.4) | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100636602; called by muse, mutect2
- RIMS1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as COSV53457314, COSV53470212; called by muse, mutect2
- RIMS1 | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1047474081, COSV53463287; called by muse, mutect2
- RIT2 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 22/334 reads (7%) | catalogued as COSV56295413; called by muse, mutect2
- RNF123 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100570392; called by muse, mutect2
- RNF213 | c.11429C>T p.S3810F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs1309296136, COSV60408826; called by muse, mutect2
- RNF214 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.158); catalogued as COSV100326548; called by muse, mutect2
- RNF215 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV99306429; called by muse, mutect2
- RP1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400757061, COSV55126523; called by muse, mutect2, varscan2
- RP1L1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100261740; called by muse, mutect2
- RRAGB | c.1022C>T p.S341F (on ENST00000262850 / NM_016656.4; = p.S313F on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV99469161; called by muse, mutect2
- RYR1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.549); catalogued as COSV100614943; called by muse, mutect2, varscan2
- SAMD14 | c.836G>A p.S279N (on ENST00000330175 / NM_001257359.2; = p.S307N on NM_174920.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.041); catalogued as COSV99142918; called by muse, mutect2
- SAMD7 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59418164; called by muse, mutect2, varscan2
- SBNO2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as rs1269969567, COSV100684217; called by muse, mutect2
- SCAPER | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as COSV100237575; called by muse, mutect2, varscan2
- SCN11A | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs768604445, COSV56570798; called by muse, mutect2, varscan2
- SCN5A | c.4266G>A p.M1422I (on ENST00000333535 / NM_198056.3; = p.M1421I on NM_000335.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV100346978; called by mutect2, varscan2
- SCN5A | c.2712G>A p.W904* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as rs1553700581, COSV100346981; called by muse, mutect2, varscan2
- SCN7A | c.4007G>A p.G1336E | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs867452341, COSV101313126; called by muse, mutect2
- SCRN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs775045104, COSV99620966; called by muse, mutect2, varscan2
- SERPINA10 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV56230060; called by muse, mutect2, varscan2
- SERTAD2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100512133; called by muse, mutect2, varscan2
- SFXN1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 15/205 reads (7%) | catalogued as COSV100369219; called by muse, mutect2
- SH2D1B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100854765; called by muse, mutect2, varscan2
- SH3D21 | c.1741C>T p.P581S (on ENST00000453908 / NM_001162530.2; = p.P470S on NM_024676.5) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99583952; called by muse, mutect2
- SH3GL3 | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100196133, COSV100196194; called by muse, mutect2, varscan2
- SHCBP1L | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62357312; called by muse, mutect2, varscan2
- SHISA3 | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100069803; called by muse, mutect2, varscan2
- SI | c.5372G>A p.G1791E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100013536; called by muse, mutect2, varscan2
- SI | c.5371G>A p.G1791R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs753703386, COSV100014451; called by mutect2, varscan2
- SI | c.4967G>A p.W1656* | Nonsense Mutation (SNP) | VAF 18/201 reads (9%) | catalogued as COSV100014455; called by muse, mutect2
- SIRT1 | c.1477T>G p.L493V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV99281634; called by muse, mutect2, varscan2
- SLC13A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs867764394, COSV52009873, COSV52015253; called by muse, mutect2, varscan2
- SLC13A4 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100818821; called by muse, mutect2
- SLC24A1 | c.1358G>A p.G453D | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755244935, COSV99978106; called by muse, mutect2, varscan2
- SLC25A18 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV100541110; called by muse, mutect2
- SLC26A3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV60642788; called by muse, mutect2
- SLC27A2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.342); catalogued as COSV51058695; called by muse, mutect2
- SLC35B3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100217230; called by muse, mutect2
- SLC39A12 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | catalogued as COSV66195886, COSV66203577; called by muse, mutect2
- SLC44A3 | c.646C>T p.L216F (on ENST00000271227 / NM_001114106.3; = p.L168F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs374306426; called by muse, mutect2, varscan2
- SLC4A8 | c.2786A>G p.K929R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as COSV100176533; called by muse, mutect2
- SLC52A3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54077278; called by muse, mutect2, varscan2
- SLC6A11 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594193; called by muse, mutect2, varscan2
- SLC7A11 | c.720T>A p.Y240* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99762978; called by muse, mutect2
- SLC9A9 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780583095, COSV57249319; called by muse, varscan2
- SLCO1A2 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV100261442; called by muse, mutect2
- SLCO6A1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV101134119; called by muse, mutect2
- SLFN13 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53194954; called by muse, mutect2
- SLITRK3 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV99578739; called by muse, mutect2
- SMARCA4 | c.4511C>T p.P1504L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787170; called by muse, mutect2
- SMR3A | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.444); catalogued as rs941824308, COSV56949852; called by muse, mutect2
- SNCAIP | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV54423585; called by muse, mutect2
- SOWAHB | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100530635; called by muse, mutect2, varscan2
- SPATA16 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV100650984; called by muse, mutect2, varscan2
- SPATA16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/158 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV63534385; called by muse, mutect2, varscan2
- SPDYA | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100477879, COSV61857891; called by muse, mutect2, varscan2
- SPEF2 | c.2963C>T p.S988L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100606644; called by muse, mutect2, varscan2
- SPEM1 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100080867; called by muse, mutect2, varscan2
- SPHKAP | c.4259C>T p.S1420L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV60879862, COSV60880669; called by muse, mutect2, varscan2
- SPIDR | c.1196A>G p.E399G | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV99854449; called by muse, mutect2, varscan2
- SPTA1 | c.3002G>A p.G1001D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.232); catalogued as rs1367973757, COSV100934554; called by muse, mutect2, varscan2
- SRARP | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1295452802, COSV100272923; called by muse, mutect2, varscan2
- SRPX | c.833A>G p.D278G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs1569204080, COSV100655949; called by mutect2, varscan2
- SRRM2 | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs777394857, COSV100070428; called by muse, mutect2, varscan2
- SSTR5 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513582; called by muse, mutect2
- ST18 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs749300022, COSV52490439; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 9/139 reads (6%) | catalogued as COSV99336297; called by muse, mutect2
- ST8SIA2 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 11/130 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV99184384; called by muse, mutect2
- STAM2 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99812909; called by muse, mutect2, varscan2
- STEAP4 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100112436; called by muse, mutect2
- STXBP5L | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.808); catalogued as COSV56499449, COSV99872607; called by muse, mutect2
- STXBP5L | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56541763; called by muse, mutect2
- STYXL2 | c.3336T>A p.F1112L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV99608756; called by muse, mutect2, varscan2
- SUGP1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367575240; called by muse, mutect2, varscan2
- SYNM | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100018498; called by muse, mutect2, varscan2
- SYNPO | c.1597A>C p.M533L (on ENST00000394243 / NM_001166208.2; = p.M289L on NM_007286.6) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100301969; called by muse, mutect2, varscan2
- SYNPO2 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100205103; called by muse, mutect2, varscan2
- TAF1B | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV99721906; called by muse, mutect2, varscan2
- TARDBP | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV99534070; called by muse, mutect2, varscan2
- TAS2R5 | c.740A>C p.Y247S | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV99924766; called by muse, mutect2, varscan2
- TBX10 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048651238, COSV100039641; called by muse, mutect2
- TCAF2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100633557; called by mutect2, varscan2
- TCF4 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1283841605, COSV100609920; called by muse, mutect2
- TEX35 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV51104455; called by muse, mutect2, varscan2
- TFAP2C | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as rs1568753299, COSV52371122; called by muse, mutect2, varscan2
- TFDP3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100033252; called by muse, mutect2, varscan2
- TGFB2 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100859924; called by muse, mutect2, varscan2
- THEMIS | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV64072891; called by muse, mutect2
- THSD7B | c.2544G>A p.M848I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99746189; called by muse, mutect2, varscan2
- TIPARP | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.328); catalogued as COSV55814106; called by muse, mutect2, varscan2
- TKT | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs782350738, COSV99964900; called by muse, mutect2, varscan2
- TLL1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50266539; called by muse, mutect2
- TMEM100 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs868028599, COSV101448213; called by muse, mutect2
- TMEM132B | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV54761873; called by muse, mutect2
- TMEM132D | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs1457475558, COSV67161039; called by muse, mutect2
- TMEM150C | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101497300; called by muse, mutect2, varscan2
- TMEM151A | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs1192754372, COSV100516847; called by muse, mutect2
- TMEM176A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866042127, COSV50240447, COSV99134008; called by muse, varscan2
- TMEM225 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV100902764, COSV100902811; called by muse, mutect2
- TNC | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100405184; called by muse, mutect2, varscan2
- TNFSF4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs372063551; called by muse, mutect2, varscan2
- TNRC6B | c.4807C>T p.P1603S (on ENST00000454349 / NM_001162501.2; = p.P1493S on NM_015088.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57292993; called by muse, mutect2, varscan2
- TPO | c.2492T>A p.L831* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | catalogued as COSV100220096; called by muse, mutect2
- TRAF5 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs748492186, COSV54822757; called by muse, mutect2, varscan2
- TRANK1 | c.5318C>T p.S1773F | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1166439561, COSV57159249; called by muse, mutect2, varscan2
- TRAV3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as rs780132095; called by muse, mutect2, varscan2
- TREM1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.02); catalogued as COSV99776110; called by muse, mutect2, varscan2
- TRIB2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99330972; called by muse, mutect2, varscan2
- TRIM58 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63571049, COSV63572027; called by muse, mutect2, varscan2
- TRIOBP | c.3319C>T p.Q1107* | Nonsense Mutation (SNP) | VAF 19/173 reads (11%) | catalogued as COSV60375813; called by muse, mutect2, varscan2
- TRIT1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100381406; called by muse, mutect2, varscan2
- TRPA1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.118); catalogued as COSV100083495, COSV51557916; called by muse, mutect2, varscan2
- TRPC6 | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.793); catalogued as COSV100723500; called by muse, mutect2
- TRPM8 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100223734; called by muse, mutect2, varscan2
- TTN | c.76882G>A p.E25628K (on ENST00000591111; = p.E18204K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/163 reads (20%) | PolyPhen possibly damaging (0.894); catalogued as COSV60114497; called by muse, mutect2, varscan2
- TTN | c.72619G>A p.D24207N (on ENST00000591111; = p.D16783N on NM_003319.4) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | PolyPhen possibly damaging (0.786); catalogued as rs763227305, COSV100599844; called by muse, mutect2, varscan2
- TTN | c.69887G>A p.G23296E (on ENST00000591111; = p.G15872E on NM_003319.4) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV59915685; called by muse, mutect2, varscan2
- TTN | c.62665G>A p.G20889R (on ENST00000591111; = p.G13465R on NM_003319.4) | Missense Mutation (SNP) | VAF 33/195 reads (17%) | PolyPhen probably damaging (0.986); catalogued as COSV59872396; called by muse, mutect2, varscan2
- TTN | c.57119G>A p.G19040E (on ENST00000591111; = p.G11616E on NM_003319.4) | Missense Mutation (SNP) | VAF 38/231 reads (16%) | PolyPhen probably damaging (1); catalogued as rs1031977069, COSV59967539; called by muse, mutect2, varscan2
- TTN | c.46597G>A p.D15533N (on ENST00000591111; = p.D8109N on NM_003319.4) | Missense Mutation (SNP) | VAF 31/373 reads (8%) | PolyPhen probably damaging (0.998); catalogued as COSV60221549; called by muse, mutect2
- TTN | c.33244C>T p.P11082S (on ENST00000591111; = p.P10155S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | PolyPhen benign (0.025); catalogued as COSV59938869; called by muse, varscan2
- TTN | c.26636C>T p.S8879L (on ENST00000591111; = p.S7952L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/252 reads (15%) | PolyPhen benign (0.05); catalogued as COSV100599854; called by muse, mutect2, varscan2
- TTN | c.16928C>T p.S5643L (on ENST00000591111; = p.S4716L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/131 reads (20%) | PolyPhen benign (0); catalogued as COSV60384340; called by muse, mutect2, varscan2
- TTN | c.8171C>T p.A2724V (on ENST00000591111; = p.A2678V on NM_003319.4) | Missense Mutation (SNP) | VAF 9/189 reads (5%) | PolyPhen probably damaging (0.997); catalogued as rs899163925, COSV60020581; called by muse, mutect2
- TTN | c.5444G>A p.R1815K (on ENST00000591111; = p.R1769K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | PolyPhen benign (0.015); catalogued as COSV59874544, COSV60371008; called by muse, mutect2, varscan2
- TTN | c.5225G>A p.G1742E (on ENST00000591111; = p.G1696E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | PolyPhen probably damaging (0.976); catalogued as COSV59996431; called by muse, varscan2
- TTN | c.5137A>G p.R1713G (on ENST00000591111; = p.R1667G on NM_003319.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | PolyPhen probably damaging (0.996); catalogued as COSV100599867; called by muse, varscan2
- TUBGCP3 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99996614; called by muse, mutect2
- TWNK | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs760229194, COSV99272090; called by muse, mutect2, varscan2
- TYRP1 | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101141225; called by muse, mutect2, varscan2
- UGT1A10 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV100761461; called by muse, varscan2
- UGT1A9 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100692099; called by muse, mutect2
- UNC13C | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs762237766, COSV99513204, COSV99518053; called by muse, mutect2, varscan2
- UROC1 | c.1790G>A p.W597* | Nonsense Mutation (SNP) | VAF 22/212 reads (10%) | catalogued as COSV99331021; called by muse, mutect2
- USP28 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50160201; called by muse, mutect2, varscan2
- USP35 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV101489056; called by muse, mutect2
- USP9X | c.5017C>T p.L1673F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV100198644; called by muse, mutect2, varscan2
- VARS2 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100422730; called by muse, mutect2
- VPS13D | c.12172C>T p.L4058F | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.568); catalogued as COSV50634379, COSV99165736; called by muse, mutect2
- WDR88 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV50131636; called by muse, mutect2, varscan2
- WHRN | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV54335515; called by muse, mutect2
- XDH | c.1388C>T p.T463I | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV101052085; called by muse, mutect2
- XDH | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149508779, COSV65150145; called by muse, varscan2
- XIRP2 | c.1966G>A p.E656K (on ENST00000628543; = p.E831K on NM_152381.6) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- XIRP2 | c.3068C>T p.S1023F (on ENST00000628543; = p.S1198F on NM_152381.6) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99739852; called by muse, mutect2
- XIRP2 | c.8329G>A p.E2777K (on ENST00000628543; = p.E2952K on NM_152381.6) | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs769725170, COSV54703994, COSV99739855; called by muse, mutect2, varscan2
- XIRP2 | c.9839C>T p.P3280L (on ENST00000628543; = p.P3455L on NM_152381.6) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1419866305, COSV99739857; called by muse, mutect2, varscan2
- XYLB | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99264039; called by muse, mutect2, varscan2
- YPEL3 | c.137G>A p.G46E (on ENST00000398838 / NM_001145524.2; = p.G84E on NM_031477.5) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99661546, COSV99661645; called by muse, mutect2, varscan2
- ZAN | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100769373; called by muse, mutect2, varscan2
- ZBBX | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs754667753, COSV56792058, COSV56792478; called by muse, mutect2, varscan2
- ZBED9 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1193619647, COSV71729198; called by muse, mutect2
- ZBTB22 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99801653; called by muse, mutect2
- ZC3HAV1 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99648328; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.501); catalogued as COSV54298314, COSV99648331; called by muse, mutect2, varscan2
- ZFPM2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV101023073; called by muse, mutect2, varscan2
- ZFX | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100457393; called by muse, mutect2, varscan2
- ZIM3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54142195, COSV99517811; called by muse, mutect2
- ZKSCAN1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.23); catalogued as COSV100164137; called by muse, mutect2, varscan2
- ZNF250 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52968835; called by muse, mutect2, varscan2
- ZNF318 | c.6167C>T p.S2056F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV58929866; called by muse, mutect2
- ZNF331 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99466999; called by muse, mutect2
- ZNF454 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV60768019; called by muse, mutect2
- ZNF536 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100834850, COSV100835743; called by muse, mutect2
- ZNF554 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV100421128; called by muse, mutect2, varscan2
- ZNF554 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57885200; called by muse, mutect2
- ZNF557 | c.977C>T p.S326L (on ENST00000414706 / NM_001044388.2; = p.S333L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs1366522171, COSV53273725; called by muse, mutect2, varscan2
- ZNF559 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV57835062; called by muse, mutect2
- ZNF578 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.658); catalogued as COSV101405021, COSV101405116; called by muse, mutect2
- ZNF611 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV60542053; called by muse, mutect2
- ZNF622 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as COSV58075547; called by muse, mutect2, varscan2
- ZNF7 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100295708; called by muse, mutect2, varscan2
- ZNF804A | c.2458C>T p.H820Y | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs750860993, COSV56449928; called by muse, mutect2, varscan2
- ZNF808 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs747776769, COSV100707831; called by muse, mutect2
- ZNF829 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as COSV66986743; called by muse, mutect2, varscan2
- AFF3 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- ALOXE3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COBLL1 | c.2300G>A p.R767K (on ENST00000392717; = p.R729K on NM_014900.5) | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.022); called by muse, mutect2
- COL28A1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.08); called by muse, mutect2
- CPNE9 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ELOVL7 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- ENAM | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2
- FBLN5 | c.633T>G p.C211W | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FRG2C | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GHR | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HEXA | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYLK | c.5220G>A p.M1740I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.085); called by muse, mutect2
- NFIA | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR8B8 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PKP2 | c.2303_2316del p.K768Rfs*8 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- ROS1 | c.6488C>T p.P2163L | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNCAIP | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF318 | c.4114C>T p.P1372S | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF605 | c.737T>A p.I246N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2
- ZNF816 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- ABCB4 | c.3831C>T p.V1277= (on ENST00000265723 / NM_018849.3; = p.V1270= on NM_000443.4) | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV55941879; called by muse, mutect2, varscan2
- AC006059.2 | c.2178C>T p.F726= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100045277; called by muse, mutect2
- AC092143.1 | c.2331C>T p.A777= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as rs200607346, COSV100205674; called by muse, mutect2, varscan2
- AC100868.1 | c.807C>T p.F269= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs950099243, COSV51846225; called by muse, mutect2, varscan2
- AC134980.2 | c.708C>T p.A236= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as COSV60907750; called by muse, mutect2
- ACAD8 | c.852C>T p.S284= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1428306905, COSV99844147; called by muse, mutect2
- ACOX2 | c.132C>T p.A44= | Silent (SNP) | VAF 32/328 reads (10%) | catalogued as COSV100250048; called by muse, mutect2
- ACTBL2 | c.912C>T p.S304= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV101379262; called by muse, mutect2
- ACTN2 | c.1725C>T p.I575= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100856606; called by muse, mutect2, varscan2
- ACTRT2 | c.792C>T p.F264= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs774983376, COSV65759185; called by muse, mutect2, varscan2
- ADAM29 | c.165C>T p.I55= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100821864, COSV63663246; called by muse, mutect2, varscan2
- ADAMTS5 | c.2250G>A p.R750= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV53184704; called by muse, mutect2, varscan2
- ADGRV1 | c.1695G>A p.V565= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV101315608; called by muse, mutect2, varscan2
- ADH7 | c.234G>A p.V78= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99265109; called by muse, mutect2
- ALDOA | c.654C>T p.I218= (on ENST00000642816 / NM_001243177.4; = p.I164= on NM_184041.5) | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100581973; called by muse, mutect2, varscan2
- AMHR2 | c.267C>T p.S89= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99143083; called by muse, mutect2, varscan2
- ANGPT1 | c.486G>A p.Q162= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99862206; called by muse, varscan2
- ANGPTL5 | c.978C>T p.H326= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as rs1156579433, COSV100527684; called by muse, mutect2
- ANK3 | c.10302C>T p.L3434= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99778826; called by muse, mutect2, varscan2
- ANK3 | c.1200C>T p.G400= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ANKIB1 | c.2347C>T p.L783= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99728585; called by muse, mutect2
- ANKRD30A | c.4011A>G p.L1337= (on ENST00000611781; = p.L1281= on NM_052997.2) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100653085; called by muse, mutect2, varscan2
- ANKZF1 | c.717G>A p.R239= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV99850347; called by muse, mutect2
- AOC1 | c.649C>T p.L217= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100710664; called by muse, mutect2, varscan2
- AP1B1 | c.102G>A p.V34= | Silent (SNP) | VAF 10/274 reads (4%) | catalogued as COSV100434444; called by muse, mutect2
- APEX2 | c.304C>T p.L102= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100895161, COSV66624075; called by muse, mutect2
- APOBEC1 | c.462G>A p.R154= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV57548869, COSV57550365; called by muse, mutect2
- APOBEC1 | c.105G>A p.E35= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99981026; called by muse, mutect2, varscan2
- APOBR | c.1179T>C p.A393= (on ENST00000431282; = p.A402= on NM_018690.4) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100112348; called by muse, mutect2
- ARAP3 | c.2526C>T p.P842= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs949471082, COSV99499429; called by muse, mutect2
- ARHGAP30 | c.2418G>A p.G806= | Silent (SNP) | VAF 42/241 reads (17%) | catalogued as COSV100920159; called by muse, mutect2, varscan2
- ATP12A | c.2922C>T p.I974= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs1389343925, COSV99517171; called by muse, mutect2, varscan2
- ATP13A4 | c.528G>A p.E176= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99794172; called by muse, mutect2
- ATP2B3 | c.3354G>A p.V1118= (on ENST00000263519 / NM_001001344.2; = p.E1170K on NM_021949.3) | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV99683450; called by muse, mutect2, varscan2
- AVP | c.51C>T p.S17= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV100977770; called by muse, mutect2
- B4GALNT2 | c.1584C>T p.D528= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs766712464, COSV100302466; called by muse, mutect2, varscan2
- BMP3 | c.1032G>A p.R344= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV99261462; called by muse, mutect2
- BNIP5 | c.153G>A p.T51= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs756773124, COSV101465103; called by muse, mutect2, varscan2
- BRINP3 | c.1885C>T p.L629= | Silent (SNP) | VAF 60/315 reads (19%) | catalogued as COSV66517530; called by muse, mutect2, varscan2
- C1QTNF7 | c.135C>T p.P45= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99765060; called by muse, mutect2, varscan2
- C7 | c.813A>G p.Q271= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57478449; called by muse, mutect2, varscan2
- CCN4 | c.642G>A p.R214= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV99136994; called by muse, mutect2, varscan2
- CCNL1 | c.1065C>T p.S355= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99904415; called by muse, mutect2
- CCNT1 | c.1458C>T p.V486= | Silent (SNP) | VAF 23/323 reads (7%) | catalogued as rs752739512, COSV99980540; called by muse, mutect2
- CCR1 | c.99G>A p.G33= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99946660; called by muse, mutect2
- CCR5 | c.633C>T p.V211= | Silent (SNP) | VAF 57/411 reads (14%) | catalogued as COSV99433201; called by muse, mutect2, varscan2
- CCSER2 | c.681C>T p.S227= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV99825605; called by muse, mutect2
- CD8B | c.354C>T p.I118= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs1473844682, COSV58926935; called by muse, mutect2
- CDH20 | c.1944A>G p.Q648= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV99404616; called by muse, mutect2
- CDH23 | c.4134C>T p.D1378= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1413176491, COSV56463490; called by muse, mutect2
- CENPQ | c.378C>T p.V126= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100225665; called by muse, mutect2
- CFAP70 | c.780C>T p.L260= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100160287; called by muse, mutect2
- CFTR | c.3099C>T p.F1033= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV50055114; called by muse, mutect2
- CGNL1 | c.1782G>A p.G594= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV99847694; called by muse, mutect2
- CHRNA3 | c.468G>A p.K156= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV100467993; called by muse, mutect2, varscan2
- CHSY3 | c.2520T>C p.P840= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100518702; called by muse, mutect2
- CIC | c.3321C>T p.P1107= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as rs1277218362, COSV50547420; called by muse, mutect2
- CLEC4M | c.348G>A p.L116= | Silent (SNP) | VAF 26/188 reads (14%) | catalogued as COSV99940417; called by muse, mutect2, varscan2
- CLSPN | c.2139C>T p.L713= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99230471; called by muse, mutect2, varscan2
- CNGB3 | c.2298A>G p.E766= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as COSV100181481; called by muse, mutect2
- CNKSR1 | c.937C>T p.L313= (on ENST00000374253 / NM_001297647.2; = p.L306= on NM_006314.3) | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs776613345, COSV100836704; called by muse, mutect2, varscan2
- CORO1A | c.1200G>A p.K400= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs757666860, COSV99531842; called by muse, mutect2, varscan2
- CPA1 | c.354C>T p.N118= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1554411241, COSV99163229; called by muse, mutect2, varscan2
- CSH2 | c.354C>T p.F118= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV61081344; called by muse, mutect2
- CUZD1 | c.1761C>T p.I587= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV100158647; called by muse, mutect2
- CYLC1 | c.1044G>A p.K348= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100254252; called by mutect2, varscan2
- CYP1A1 | c.729A>C p.L243= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV101122245; called by muse, mutect2, varscan2
- CYP4F12 | c.1500G>A p.R500= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV61175630; called by muse, mutect2
- CYYR1 | c.459G>A p.R153= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs373523110; called by muse, mutect2, varscan2
- DCAF4L2 | c.117C>T p.F39= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs779092689, COSV60476339; called by muse, mutect2, varscan2
- DCDC1 | c.2628C>T p.G876= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100337956; called by muse, mutect2
- DCSTAMP | c.870G>A p.R290= | Silent (SNP) | VAF 29/203 reads (14%) | catalogued as COSV52577351; called by muse, mutect2, varscan2
- DENND2C | c.1638G>A p.K546= (on ENST00000393274 / NM_001256404.2; = p.K489= on NM_198459.4) | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101283902, COSV67924420; called by muse, mutect2
- DLEC1 | c.3861C>T p.I1287= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100341701; called by muse, mutect2
- DMXL2 | c.4599C>T p.F1533= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV51843172; called by muse, mutect2, varscan2
- DNAH3 | c.6843G>A p.V2281= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs868304975, COSV54516297; called by muse, mutect2, varscan2
- DNAH3 | c.4186C>T p.L1396= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs1255817622, COSV99765660; called by muse, mutect2, varscan2
- DNAH7 | c.10779G>A p.R3593= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV56756971; called by muse, mutect2, varscan2
- DOCK2 | c.1008G>A p.G336= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV99910851, COSV99915309; called by muse, mutect2
- DOP1B | c.2478C>T p.S826= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV101215142; called by muse, mutect2
- DPH7 | c.762C>T p.I254= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99483405; called by muse, mutect2
- DSCAML1 | c.1524C>T p.I508= (on ENST00000321322; = p.I448= on NM_020693.4) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs749437030, COSV100355071; called by muse, mutect2, varscan2
- DSP | c.8259G>A p.K2753= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as rs1005570207, COSV60940774; called by muse, mutect2
- EIF2AK4 | c.3120C>T p.S1040= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs777664600, COSV99774267; called by muse, mutect2, varscan2
- EIF3I | c.12C>T p.I4= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV100557130; called by muse, mutect2
310 further variants in this file (0 protein-altering or splice-affecting, 289 silent, 21 other) are not listed here.
